Surgical pathology report (de-identified scan), TCGA case TCGA-24-1435, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1435-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient Name:

Address

Service

Accession

) Location

Taken:

Gender:

MRN

Received: i

DOB:

Hospital #:

Reported:

Patient Type:

Physician(s):

TCGA-24-1435

Other Related Clinical Data:

DIAGNOSIS: SPECIMEN LABELED "RIGHT ADNEXAL MASS," EXCISION

- PORTION OF OVARY WITH PAPILLARY SEROUS ADENOCARCINOMA

- PORTION OF FALLOPIAN TUBE WITH PAPILLARY SEROUS ADENOCARCINOMA IN PERITUBAL SOFT TISSUE

OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- PAPILLARY SEROUS ADENOCARCINOMA

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA INVOLVING FALLOPIAN TUBE EPITHELIUM AND PERITUBAL SOFT TISSUE

OVARY, LEFT, OOPHORECTOMY

- PAPILLARY SEROUS ADENOCARCINOMA

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- PAPILLARY SEROUS ADENOCARCINOMA (SEE COMMENT)

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- LEIOMYOMAS

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

OMENTUM, INFRA-COLIC AND GASTRIC, EXCISION

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

[page 2 of 3]
[REDACTED]

C: COLONIC MESENTERIC LYMPH NODE
D: LEFT OVARY, FS1
E: RIGHT ADNEXAL TUMOR
F: COLONIC NODULE
G: UTERUS, CERVIX, RIGHT OVARY
H: COLONIC NODULE

Gross Description The specimens are received in eight containers of formalin, each labelled with the patient's name. The first is labelled "vulvar biopsy" and contains a single piece of pink-tan tissue measuring 0.3 cm in diameter. Wrapped in filter paper. [REDACTED]

The second container is labelled "infra-colonic gastric omentum." It contains a segment of resected omentum measuring 34.0 x 5.0 x 3.0 cm in greatest dimension, which contains multiple pink-white tumor nodules, measuring 0.3 to 3.0 cm in diameter. On sectioning, these nodules appear pink-tan-yellow, solid, and partially inhomogeneous. Some of these nodules appear to be cystic with small intracystic papillary structures present. [REDACTED]

The third container is labelled "colonic mesenteric lymph nodes." It contains a single piece of fibroadipose tissue measuring 3.3 x 1.6 x 1.5 cm in greatest dimension, within which three putative lymph nodes are dissected. [REDACTED]

The fourth container is labelled "left ovary, FS1" and contains a collection of pink-tan tissue fragments measuring 5.0 x 3.5 x 1.7 cm in aggregate. No grossly identifiable ovarian tissue is present. On section, these tissue fragments appear pink-tan, solid, and homogenous. Also present in the specimen container is a white cassette, which contains a single piece of pink-tan tissue fragment (2.2 x 1.5 x 0.3 cm in greatest dimension) with similar growth features as those described above. This particular piece of tissue appears to be the frozen section remnant. Labelled D1, remainder of frozen section tissue [REDACTED] sections of the left ovarian tissue. [REDACTED]

The fifth container is labelled "right adnexal tumor" and contains a piece of pink-tan tissue measuring 6.0 x 5.4 x 2.5 cm in greatest dimension, which has smooth external surface on one side. The specimen appears to have been previously sectioned. Sections of the tissue show multilocular cystic lesions, 0.7 to 1.8 cm in diameter, which have a smooth internal surface with yellow-tan clear fluid. In addition, multiple ill-defined nodules (0.7 to 1.2 cm in diameter) are also identified either within the cyst wall or underneath the external surface. Also present in the container is a small tissue fragment measuring 1.7 x 1.2 x 1.2 cm in greatest dimension, which is pink-tan, solid, and homogenous on sectioning. Labelled E1-E4, sections of the right adnexal tumor; E5, sections of smaller tissue fragment. [REDACTED]

The sixth container is labelled "colonic nodule" and contains a collection of irregularly-shaped, pink-tan tissue fragments measuring 3.0 x 2.0 x 1.5 cm in aggregate. Sections of the tissue show pink-tan, solid, and homogenous cut surfaces. Labelled F1-F3. [REDACTED]

The seventh container is labelled "uterus, cervix, right ovary." It contains a resected uterus with attached right ovary and fallopian tube. The entire specimen weighs 80 grams. The cervix (2.8 x 3.0 x 2.7 cm in greatest dimension) has an overall smooth and hyperemic ectocervical surface measuring 3.1 x 3.6 cm in area. The ectocervical os measures 0.3 cm in diameter. The endocervical canal measures 1.5 cm in length and 0.4 cm in diameter, and appears grossly unremarkable. The corpus uteri measures 5.0 x 5.5 x 2.8 cm in greatest dimension and appears symmetric with an overall smooth serosal surface except through a focal area at the right anterior surface where nodulated adhesions (2.8 x 1.4 cm in area) are noted. The endometrial cavity measures 3.8 x 2.5 cm in greatest dimension and is

[page 3 of 3]
19. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM Scheme	FIGO Scheme	Definition	Macroscopic
T3c		IIIC	
peritoneal metastasis beyond true pelvis measuring > 2 cm in greatest dimension, OR Regional lymph node metastasis OR Metastasis to capsule of liver.			

THE REGIONAL LYMPH NODES are classified as: NX (Nodal status cannot be assessed)

THE STATUS OF DISTANT TUMOR SITES is classified as: MX (Status cannot be assessed)

20. [REDACTED]

X Insufficient data to assign stage

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 13f29982-d6e0-45b9-8c18-b792434b55ff (TCGA-24-1435.D1574B6C-6CC1-45BC-86D0-97585D8A5C93.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).